Gene-level copy-number profile of tumor specimen TCGA-D8-A147-01A from TCGA case TCGA-D8-A147, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.8 years (16,736 days).
Specimen TCGA-D8-A147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.92830f47-3f32-4b74-bef4-4536963be38f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A147-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/030c1047-3045-490d-8597-c4c602b1ece0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,209; copy number 2: 12,199; copy number 3: 23,063; copy number 4: 7,648; copy number 5: 6,309; copy number 6: 6,647; copy number 7: 1,546; copy number 8: 365; copy number 9: 163; copy number 10: 36; copy number 11: 263; copy number 14: 360.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A147-01A-11D-A111-01): tumor purity 0.57, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,733 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,937,812–169,103,276, 755 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:168,938,467–168,938,923, 1 gene, copy number 7: RPL29P7.
- chr1:221,701,424–248,919,946, 665 genes, copy number 7–14 (broad region; genes not listed).
- chr2:60,336,446–60,439,828, 4 genes, copy number 7: MIR4432HG, AC007381.1, RNU1-32P, MIR4432.
- chr2:101,252,886–101,894,689, 13 genes, copy number 7: CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4.
- chr2:201,487,421–202,038,445, 21 genes, copy number 7 (within-gene range 6–7): C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11, RNU6-440P, AC069148.1, FZD7.
- chr2:241,227,264–242,160,153, 39 genes, copy number 8 (within-gene range 4–8): HDLBP, SEPTIN2, AC104841.1, AC005104.1, FARP2, AC005104.2, MIR3133, KCTD5P1, STK25, BOK-AS1, BOK, AC133528.1, THAP4, RNA5SP122, ATG4B, DTYMK, ING5, AC114730.3, D2HGDH, AC114730.1, AC114730.2, GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5, LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr3:191,199,241–198,222,513, 194 genes, copy number 7–10 (broad region; genes not listed).
- chr6:17,737,458–21,232,404, 40 genes, copy number 9 (within-gene range 6–9): Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P.
- chr6:89,059,628–93,419,559, 55 genes, copy number 7 (within-gene range 5–7): AL079342.2, RNU2-61P, AL353135.1, PNRC1, RN7SL336P, SRSF12, AL353135.2, PM20D2, GABRR1, GABRR2, TUBB3P1, UBE2J1, RRAGD, NACAP7, ANKRD6, RN7SL11P, AL159174.1, LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7, AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7.
- chr9:114,572,901–115,402,644, 14 genes, copy number 8 (within-gene range 5–8): AL160275.2, ATP6V1G1, TMEM268, Y_RNA, TEX53, TEX48, AL160275.1, AL390240.1, TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1.
- chr10:30,012,803–32,394,665, 56 genes, copy number 7: JCAD, RNU6-598P, EEF1A1P39, AL353796.1, MTPAP, AL353796.2, DNM1P17, GOLGA2P6, RN7SL241P, MIR7162, NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3, LYZL2, SVIL2P, LINC02644, ZNF438, AL359532.1, DDX10P1, AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.3, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P.
- chr10:42,279,734–42,475,349, 4 genes, copy number 14: PABPC1P8, BX322639.1, CCNYL2, AL391099.1.
- chr10:83,708,841–88,049,823, 95 genes, copy number 7 (broad region; genes not listed).
- chr17:66,964,707–68,955,392, 60 genes, copy number 9: CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8.
- chr19:21,932,958–33,927,625, 238 genes, copy number 7–11 (broad region; genes not listed).
- chr19:36,111,151–45,526,983, 479 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
